Somatic mutation profile of tumor specimen 0DG87M from CCDI case PBBRDG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,254 days).
Specimen 0DG87M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d324223-9549-4b23-b05c-0596fb57dd2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4496320-1c88-44ee-b818-da0fb98b696f

The open-access MAF lists 10 somatic variants for this specimen: 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 8, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, varscan2
- DDX60 | c.4270-45T>A | Intron (SNP) | VAF 8/79 reads (10%) | called by muse, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 8/43 reads (19%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 8/41 reads (20%) | called by muse, varscan2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 8/73 reads (11%) | called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 22/118 reads (19%) | called by muse, varscan2
- SLC44A1 | c.*76G>T | 3'UTR (SNP) | VAF 20/192 reads (10%) | catalogued as rs1397530404, COSV100570405; called by muse, varscan2
- TNK2 | c.1543+499G>C | Intron (SNP) | VAF 37/134 reads (28%) | called by muse, varscan2
- ZGRF1 | c.2802+51C>T | Intron (SNP) | VAF 29/271 reads (11%) | called by muse, varscan2
